Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6362, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6362-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. LEFT PELVIC LYMPH NODE
- B. RIGHT PELVIC LYMPH NODE
- C. LEFT PELVIC LYMPH NODES
- D. PROSTATE

TCGA - G9 - 6362

SPECIMEN(S):

- A. LEFT PELVIC LYMPH NODE
- B. RIGHT PELVIC LYMPH NODE
- C. LEFT PELVIC LYMPH NODES
- D. PROSTATE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

TPA, Left pelvic lymph node, bx: No malignancy identified
FSB, Right pelvic lymph node, bx: Negative for tumor
FSC, Left pelvic lymph nodes, bx: Negative for tumor
Diagnoses called at [REDACTED] (A and B) by Dr., and [REDACTED] (C) by Dr.

GROSS DESCRIPTION:

A. LEFT PELVIC LYMPH NODE

Received fresh labeled with the patient's identification and designated "left pelvic lymph node" is a fragment of fibroadipose tissue measuring 1.5 x 0.8 x 0.4 cm. No lymph node is grossly appreciated. Touch preparation performed. The entire specimen is submitted, A1.

B. RIGHT PELVIC LYMPH NODE

Received fresh labeled with the patient's identification and designated "right pelvic lymph node" is a 3.2 x 2.2 x 1 cm fragment of fibroadipose tissue showing one lymph node measuring 1.3 x 0.5 x 0.4 cm. The lymph node is bisected, touch preparation performed. The entire lymph node is submitted for frozen section, [REDACTED]

C. LEFT PELVIC LYMPH NODES

Received fresh labeled with the patient's identification and designated "left pelvic lymph nodes" is a 4 x 2.5 x 1.2 cm fragment of fibroadipose tissue showing a possible lymph node measuring 1.2 x 0.8 x 0.2 cm. The lymph node is bisected, submitted entirely for frozen section, [REDACTED]

D. PROSTATE

Received fresh labeled with the patient's identification and designated "prostate" is a resected prostate gland weighing 40 g and measuring 5-cm from right to left, 3.8-cm from anterior to posterior, and 2.6-cm from apex to base. The capsule is smooth, red, and intact. Ink code: Apex-red, anterior-orange, posterior-black, base-blue, right-green, left-yellow. The apex and base are removed from the specimen yielding a new weight of 21 g. The specimen is serially sectioned from apex to base revealing firm tan fibrous parenchyma. The right and left seminal vesicle, 5 x 1 x 0.3 cm and 6.2 x 1.5 x 0.3 cm, respectively, are bisected to show beige tan cystic tissue. The right and left vas deferens, 1.1 x 0.5 cm and 0.8 x 0.5 cm, respectively, are serially sectioned to show firm tan tube structure. A portion of the specimen is submitted for tissue procurement, the remainder is entirely submitted:

D1-D2: Right apex

D3-D4: Left Apex

D5: Level 1 right anterior

D6: Level 1 right posterior

D7: Level 1 left anterior

D8: Level 1 left posterior

D9-D10: Level 2 capsule, right side

D11-D12: Level 2 capsule, left side

D13-D14: Right lateral base

D15-D17: Right base

D18: Right base with proximal urethral margin

D19: Left base with proximal urethral margin

D20-D21: Left base

D22: Left lateral base

D23: Right seminal vesicle, right vas, representative sections

D24: Left seminal vesicle, left vas, representative sections

DIAGNOSIS:

- A. LYMPH NODES, LEFT PELVIC, EXCISION:
- FIBROADIPOSE TISSUE WITHIN NORMAL LIMITS; NO LYMPH NODE(S) IDENTIFIED.

[page 2 of 2]
B. LYMPH NODES, RIGHT PELVIC, EXCISION:

- ONE LYMPH NODE WITH NO EVIDENCE OF ADENOCARCINOMA (0/1).

C. LYMPH NODES, LEFT PELVIC, EXCISION:

- ONE LYMPH NODE WITH NO EVIDENCE OF ADENOCARCINOMA (0/1).

D. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 4 + 3 (7/10) WITH A TERTIARY COMPONENT OF GRADE 5, INVOLVING THE LEFT AND RIGHT LOBES AND WITH EXTENSIVE EXTRACAPSULAR INVOLVEMENT.
- MARGINS WIDELY POSITIVE FOR ADENOCARCINOMA IN NUMEROUS LOCATIONS INCLUDING THE RIGHT AND LEFT APEX AND POSTEROLATERAL CAPSULAR MARGINS.
- RIGHT AND LEFT SEMINAL VESICLES NEGATIVE FOR ADENOCARCINOMA.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: D: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 65%

Gleason Grade/Sum:: Grade 4 + 3 , Sum 7 /10; Tertiary grade 5

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

Details: LEFT ANTERIOR, RIGHT POSTERIOR

Bladder Neck Involved: No

Margins Involvement: Yes

Location:

MULTIPLE LOCATIONS - RIGHT AND LEFT APEX AND POSTEROLATERAL

Linear Distance: Diffuse (>10mm or Multifocal)

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 1 Left 0 / 1

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 3a N 0 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate carcinoma

Source: NCI Genomic Data Commons file fa0661bd-bfc2-49ab-9539-99eaef6c671b (TCGA-G9-6362.FC8BAC85-E3C5-47C1-B4C1-9B8834E01780.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).